Somatic mutation profile of tumor specimen C3L-03462-01 (aliquot CPT0190070006) from CPTAC case C3L-03462, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 61.5 years (22,465 days).
Specimen C3L-03462-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b887790-8cac-4927-90a4-5acdad62bbc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03462-31 (Blood Derived Normal), aliquot CPT0191180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e00e7ea-033c-4c40-bb00-bcc095537faa

The open-access MAF lists 218 somatic variants for this specimen: 156 protein-altering or splice-affecting, 35 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 35, Intron 14, Nonsense Mutation 11, 3'UTR 4, RNA 4, Frame Shift Del 3, 5'UTR 3, Splice Region 2, Splice Site 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/478 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 91/602 reads (15%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1706G>T p.R569M | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59371236; called by muse, mutect2
- ADAMTSL1 | c.4225G>T p.D1409Y | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV101000518; called by muse, mutect2, varscan2
- AQP2 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.366); catalogued as rs1318426281; called by muse, mutect2, varscan2
- BCL11B | c.1078G>A p.A360T (on ENST00000357195 / NM_001282237.2; = p.A289T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.394); catalogued as rs1421392915, COSV100595152, COSV100596012; called by muse, mutect2, varscan2
- BRAF | c.1525G>T p.G509* (on ENST00000288602 / NM_001374244.1; = p.G469* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 78/482 reads (16%) | catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1QTNF12 | c.771G>C p.R257S | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs757149209; called by muse, mutect2, varscan2
- CENPC | c.2190G>T p.L730F | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99893961; called by muse, mutect2
- CLPTM1L | c.307A>T p.T103S | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.605); catalogued as COSV100307190; called by muse, mutect2, varscan2
- CNTN3 | c.1596C>G p.I532M | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs767477939; called by muse, mutect2, varscan2
- COL20A1 | c.3221C>A p.P1074Q | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58930107; called by muse, mutect2, varscan2
- CR2 | c.2804C>A p.A935D | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100889680; called by muse, mutect2
- CRACD | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.112); catalogued as rs185302995; called by muse, varscan2
- CRLS1 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs1224313830; called by mutect2, varscan2
- DCTN1 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as CM162917; called by muse, mutect2, varscan2
- EMC1 | c.2206C>G p.L736V | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs768141678; called by muse, mutect2, varscan2
- EYS | c.2147G>T p.G716V | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV65498996; called by muse, mutect2
- FAT4 | c.9418G>A p.A3140T | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs937627621; called by muse, mutect2, varscan2
- FLG2 | c.4779C>A p.H1593Q | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1349168639; called by muse, mutect2, varscan2
- FZD10 | c.436C>A p.L146M | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.533); catalogued as COSV57473718; called by muse, mutect2, varscan2
- GATA3 | c.1281C>A p.S427R | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100651264; called by muse, mutect2, varscan2
- GRB10 | c.1499G>T p.R500M (on ENST00000398812; = p.R454M on NM_001001549.3) | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60010205; called by muse, mutect2, varscan2
- GRHL1 | c.1727A>G p.K576R | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs750025069; called by muse, mutect2
- HNRNPCL2 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60403554; called by muse, mutect2, varscan2
- IFI16 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.288); catalogued as rs770364590; called by muse, mutect2, varscan2
- KCNN1 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs764917737; called by muse, mutect2, varscan2
- KIF4B | c.2204G>T p.G735V | Missense Mutation (SNP) | VAF 52/532 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV101469403; called by muse, mutect2
- KLHDC1 | c.956A>G p.K319R | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.971); catalogued as rs1174547921; called by muse, mutect2
- KRTAP21-2 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV100441310; called by muse, varscan2
- LRIT2 | c.958G>C p.V320L | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.087); catalogued as COSV60565396; called by muse, mutect2, varscan2
- MFSD5 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1334595405; called by muse, mutect2, varscan2
- MXRA5 | c.1694G>C p.R565P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.53); catalogued as COSV99476977; called by muse, mutect2, varscan2
- NID2 | c.3503G>A p.R1168H | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs955417276; called by muse, mutect2
- NID2 | c.3502C>A p.R1168S | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as rs117206856; called by muse, mutect2
- OR10J3 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV59954098; called by muse, mutect2, varscan2
- OR2A2 | c.455T>C p.F152S | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as rs1487291439; called by muse, mutect2
- OR2T4 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 102/682 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV63543913; called by mutect2, varscan2
- OR5AS1 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV57983221; called by muse, mutect2
- OR5D14 | c.477G>T p.L159F | Missense Mutation (SNP) | VAF 67/366 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV59455226; called by muse, mutect2, varscan2
- OR5L2 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV101004346; called by muse, mutect2, varscan2
- OR5L2 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV101004372; called by muse, mutect2, varscan2
- PCDH15 | c.2923C>G p.P975A | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.078); catalogued as COSV57280092, COSV57397676; called by muse, mutect2, varscan2
- PCDHB4 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 97/997 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438925892, COSV52025929; called by muse, mutect2
- PDZRN4 | c.2816G>A p.R939H (on ENST00000402685 / NM_001164595.2; = p.R681H on NM_013377.4) | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755141579, COSV54193075; called by muse, mutect2, varscan2
- PEDS1 | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs931753734; called by muse, mutect2, varscan2
- PIWIL1 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55345426; called by muse, mutect2, varscan2
- PTPN18 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.116); catalogued as rs766427031; called by muse, mutect2, varscan2
- PYHIN1 | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV63721236, COSV63721402; called by muse, varscan2
- RELN | c.3311G>T p.G1104V | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58986070; called by muse, mutect2, varscan2
- RIPOR3 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs572110299, COSV50397631; called by muse, mutect2, varscan2
- SCP2D1 | c.19C>A p.H7N | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as rs1477923351; called by muse, mutect2, varscan2
- SPTBN5 | c.8110G>T p.V2704L | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs1441892028; called by muse, mutect2, varscan2
- VWC2 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.025); catalogued as COSV100514480; called by muse, mutect2, varscan2
- ZNF93 | c.1708T>C p.C570R | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs757925637; called by muse, mutect2
- ABHD18 | c.209A>C p.D70A | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ACSM5 | c.21C>A p.H7Q | Missense Mutation (SNP) | VAF 51/338 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, varscan2
- ANK3 | c.9594C>G p.S3198R | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ANKRD18B | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ANKRD60 | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARID1A | c.2941del p.M981* | Frame Shift Del (DEL) | VAF 23/174 reads (13%) | called by mutect2, pindel, varscan2
- ARMC2 | c.1826G>T p.R609L | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATG2B | c.5202G>T p.M1734I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2A3 | c.284T>C p.M95T | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BASP1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- BRCA1 | c.1987A>T p.S663C | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CD109 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDH8 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 79/341 reads (23%) | called by muse, mutect2, varscan2
- CFAP54 | c.5609C>A p.T1870K | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CGGBP1 | c.213G>C p.K71N | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- COBLL1 | c.2080C>T p.Q694* (on ENST00000392717; = p.Q656* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- CR2 | c.2615C>T p.P872L | Missense Mutation (SNP) | VAF 67/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CREB1 | c.437C>T p.P146L (on ENST00000432329 / NM_134442.5; = p.P132L on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, varscan2
- CRYGD | c.205T>A p.W69R | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYFIP2 | c.1441G>C p.A481P | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DMGDH | c.1573G>T p.V525F | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DNAH17 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPS8L2 | c.895+6G>T | Splice Region (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- FAM189A1 | c.1505G>T p.C502F | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- FAM83B | c.2473G>T p.D825Y | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- FAT4 | c.11516T>C p.I3839T | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2
- FSIP2 | c.6117T>A p.S2039R | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- GRIA4 | c.1758C>A p.S586R | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- GRM8 | c.1933A>G p.T645A | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GRM8 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF3C5 | c.1168-4C>T | Splice Region (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- HIBADH | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HOOK3 | c.223A>T p.N75Y | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA7 | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IFFO2 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, varscan2
- IGHG2 | c.828G>T p.M276I | Missense Mutation (SNP) | VAF 160/1047 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, varscan2
- JCAD | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 50/300 reads (17%) | called by muse, mutect2, varscan2
- KATNIP | c.4688A>T p.H1563L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KIF4B | c.2203G>T p.G735* | Nonsense Mutation (SNP) | VAF 52/531 reads (10%) | called by muse, mutect2
- KIF4B | c.3335G>T p.C1112F | Missense Mutation (SNP) | VAF 40/459 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- KIZ | c.1604G>T p.R535M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); called by muse, mutect2
- KRTAP9-7 | c.154T>A p.C52S | Missense Mutation (SNP) | VAF 82/367 reads (22%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- LRP2 | c.13042G>A p.G4348R | Missense Mutation (SNP) | VAF 90/510 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K7CL | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- MPC1 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MSTN | c.761A>T p.E254V | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- MYLK3 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 66/930 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.251); called by muse, mutect2
- NCAM2 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- OR2T8 | c.481A>C p.T161P | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- OR4A5 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- OR6T1 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 59/444 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- OTOA | c.1225G>T p.V409L (on ENST00000286149; = p.V395L on NM_144672.4) | Missense Mutation (SNP) | VAF 76/630 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- PARG | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PAX2 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDH11X | c.3749C>A p.A1250E | Missense Mutation (SNP) | VAF 142/496 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH18 | c.1147A>T p.R383* | Nonsense Mutation (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- PCDHB3 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 132/998 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PCDHGA3 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCK1 | c.841del p.A281Rfs*15 | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | called by mutect2, pindel, varscan2
- PNLIPRP2 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR3A | c.2655G>T p.Q885H | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POU3F3 | c.1238T>C p.I413T | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R2B | c.159G>T p.L53F | Missense Mutation (SNP) | VAF 66/725 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PPP4R3C | c.1666T>A p.C556S | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PPP6R1 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PTPRD | c.3023G>T p.S1008I | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2
- RAG2 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- RDH11 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RRM1 | c.1395G>T p.K465N | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- RYR2 | c.5527T>G p.L1843V | Missense Mutation (SNP) | VAF 15/391 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RYR2 | c.6898G>T p.D2300Y | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN11A | c.267+2T>C p.X89_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | called by muse, varscan2
- SCUBE2 | c.767A>T p.E256V | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SGCD | c.662G>C p.R221T (on ENST00000435422 / NM_001128209.2; = p.R222T on NM_000337.5) | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC30A6 | c.1013G>T p.R338M | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SLITRK2 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SND1 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.021); called by muse, mutect2
- SPATA31D1 | c.2842G>A p.A948T | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.316); called by muse, mutect2
- SVEP1 | c.8680C>A p.P2894T | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TCERG1L | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- TENM3 | c.1965C>A p.H655Q | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- TLE3 | c.233A>G p.Q78R | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM114 | c.631del p.R211Afs*5 | Frame Shift Del (DEL) | VAF 24/244 reads (10%) | called by mutect2, pindel, varscan2
- TNXB | c.9725T>A p.V3242E (on ENST00000647633; = p.V2995E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/369 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TRAK1 | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- TRAV21 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- TRIM24 | c.1195G>C p.V399L | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIM37 | c.359G>C p.W120S | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- TRIM49B | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTC14 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 38/171 reads (22%) | called by muse, mutect2, varscan2
- UBXN4 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2
- USH2A | c.8562T>A p.Y2854* | Nonsense Mutation (SNP) | VAF 36/296 reads (12%) | called by muse, mutect2, varscan2
- VCAN | c.1722C>G p.D574E | Missense Mutation (SNP) | VAF 48/475 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- VPS51 | c.1963C>G p.R655G | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2
- WDFY4 | c.4693G>T p.E1565* | Nonsense Mutation (SNP) | VAF 57/494 reads (12%) | called by muse, mutect2, varscan2
- WDR45 | c.858G>C p.M286I (on ENST00000376372 / NM_001029896.2; = p.M287I on NM_007075.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- XIRP2 | c.9679C>A p.P3227T (on ENST00000628543; = p.P3402T on NM_152381.6) | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF385B | c.1375G>C p.A459P | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- ZNF488 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- ZNF570 | c.939G>C p.Q313H | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF577 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ABCA9 | c.1878A>T p.L626= | Silent (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.1413C>T p.I471= | Silent (SNP) | VAF 23/249 reads (9%) | catalogued as COSV61257710; called by muse, mutect2
- AMN | c.369G>A p.E123= | Silent (SNP) | VAF 76/456 reads (17%) | called by muse, mutect2, varscan2
- ASXL1 | c.2298C>A p.S766= | Silent (SNP) | VAF 52/337 reads (15%) | called by muse, mutect2, varscan2
- BTNL2 | c.18C>A p.G6= | Silent (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- CFAP46 | c.4575C>A p.V1525= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as rs765119403; called by muse, mutect2, varscan2
- COL11A2 | c.3498G>A p.E1166= (on ENST00000341947 / NM_080680.3; = p.E1059= on NM_080679.2) | Silent (SNP) | VAF 97/632 reads (15%) | catalogued as COSV59497918; called by muse, mutect2, varscan2
- DAPK3 | c.693C>T p.A231= | Silent (SNP) | VAF 43/293 reads (15%) | catalogued as rs375852405; called by muse, mutect2, varscan2
- DRD2 | c.1035C>A p.T345= | Silent (SNP) | VAF 98/714 reads (14%) | called by muse, mutect2, varscan2
- ETV1 | c.598T>C p.L200= | Silent (SNP) | VAF 38/295 reads (13%) | called by muse, mutect2, varscan2
- F5 | c.510C>T p.H170= | Silent (SNP) | VAF 104/602 reads (17%) | catalogued as rs375660526; called by muse, mutect2, varscan2
- FAM174A | c.57C>T p.L19= | Silent (SNP) | VAF 27/320 reads (8%) | catalogued as rs577301081; called by muse, mutect2
- FPR2 | c.90G>A p.L30= | Silent (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- HS3ST4 | c.882C>A p.A294= | Silent (SNP) | VAF 26/274 reads (9%) | called by muse, mutect2
- LAS1L | c.1185G>T p.T395= | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as COSV56706447, COSV56706723; called by muse, mutect2, varscan2
- LCE3C | c.51C>A p.P17= | Silent (SNP) | VAF 46/375 reads (12%) | called by muse, mutect2, varscan2
- MUC21 | c.798G>C p.G266= | Silent (SNP) | VAF 107/785 reads (14%) | called by muse, mutect2, varscan2
- NAPSA | c.1131C>T p.F377= | Silent (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- OR5AR1 | c.54C>A p.T18= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV57255102; called by muse, mutect2
- OVCH1 | c.3081G>A p.P1027= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs370527130; called by muse, mutect2, varscan2
- PDE6A | c.1479G>T p.A493= | Silent (SNP) | VAF 38/243 reads (16%) | catalogued as COSV99678024; called by muse, mutect2, varscan2
- PDZD2 | c.7989G>C p.G2663= | Silent (SNP) | VAF 30/275 reads (11%) | called by muse, mutect2, varscan2
- POU6F1 | c.915C>G p.T305= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV100374752; called by muse, mutect2, varscan2
- PRKCG | c.273C>A p.G91= | Silent (SNP) | VAF 73/477 reads (15%) | catalogued as COSV54724284; called by muse, mutect2, varscan2
- RSPO1 | c.708T>C p.G236= | Silent (SNP) | VAF 38/438 reads (9%) | catalogued as rs1431758999; called by muse, mutect2
- RSPRY1 | c.504A>G p.P168= | Silent (SNP) | VAF 40/137 reads (29%) | called by muse, mutect2, varscan2
- SFRP5 | c.588G>A p.Q196= | Silent (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- SH3D21 | c.126G>T p.G42= | Silent (SNP) | VAF 44/280 reads (16%) | called by muse, mutect2, varscan2
- TBC1D5 | c.2250C>T p.A750= | Silent (SNP) | VAF 46/338 reads (14%) | called by muse, mutect2, varscan2
- TBX19 | c.771A>T p.A257= | Silent (SNP) | VAF 67/597 reads (11%) | called by muse, mutect2, varscan2
- TPBGL | c.12C>A p.R4= | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- TTLL9 | c.291G>T p.R97= | Silent (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- TTYH1 | c.471C>A p.T157= | Silent (SNP) | VAF 41/242 reads (17%) | called by muse, mutect2, varscan2
- ZFP41 | c.282G>A p.R94= | Silent (SNP) | VAF 59/274 reads (22%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.681G>T p.V227= | Silent (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2, varscan2
- AC136604.1 | n.506G>T | RNA (SNP) | VAF 42/500 reads (8%) | called by muse, mutect2
- AL353804.7 | chrX:73846784 T>A | 5'Flank (SNP) | VAF 34/195 reads (17%) | catalogued as rs1262352973; called by muse, mutect2, varscan2
- ANKIB1 | c.-436T>C | 5'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- AP000356.3 | n.710G>A | RNA (SNP) | VAF 104/576 reads (18%) | catalogued as rs1370927795; called by muse, mutect2, varscan2
- AP002495.1 | c.436+383A>T | Intron (SNP) | VAF 12/47 reads (26%) | catalogued as rs1393637488; called by muse, mutect2, varscan2
- B4GALNT3 | c.352-1182A>T | Intron (SNP) | VAF 26/241 reads (11%) | called by muse, varscan2
- CABP1 | c.655-32C>A | Intron (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- CD79B | c.*31G>T | 3'UTR (SNP) | VAF 42/293 reads (14%) | called by muse, mutect2, varscan2
- CDK15 | c.1009+5813A>C | Intron (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- DPP6 | c.627+20830G>T | Intron (SNP) | VAF 43/323 reads (13%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-4697C>A | Intron (SNP) | VAF 44/261 reads (17%) | called by muse, mutect2, varscan2
- GORAB | c.*448A>G | 3'UTR (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- GSDME | c.404+19C>T | Intron (SNP) | VAF 28/284 reads (10%) | called by muse, mutect2
- HBE1 | c.-267+74653A>T | Intron (SNP) | VAF 67/451 reads (15%) | called by muse, mutect2, varscan2
- HDAC8 | c.738-3206A>T | Intron (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- IGFBP5 | c.338-55T>A | Intron (SNP) | VAF 34/158 reads (22%) | called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.256C>T | RNA (SNP) | VAF 47/290 reads (16%) | called by muse, mutect2, varscan2
- LINC02118 | n.214G>C | RNA (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- MTERF4 | c.-14A>G | 5'UTR (SNP) | VAF 50/327 reads (15%) | catalogued as rs766935642; called by muse, mutect2, varscan2
- NPAS3 | c.558+18042G>T | Intron (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4813T>A | Intron (SNP) | VAF 100/652 reads (15%) | called by muse, mutect2, varscan2
- PPARG | c.620-6525A>G | Intron (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2, varscan2
- RHBDL2 | c.-190G>T | 5'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2
- TP63 | c.580-19898G>C | Intron (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- VAPB | c.*2476T>C | 3'UTR (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2, varscan2
- VRK3 | chr19:49971872 C>A | 3'Flank (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- ZIC4 | c.*8C>A | 3'UTR (SNP) | VAF 39/188 reads (21%) | called by muse, mutect2, varscan2
